Gene-level copy-number profile of tumor specimen TCGA-2G-AAFB-01A from TCGA case TCGA-2G-AAFB, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IB; Age at diagnosis: 30.5 years (11,146 days).
Specimen TCGA-2G-AAFB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b445891e-ed4a-4ae0-9b0d-2208049a0d45.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-2G-AAFB-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,707 have no estimate.
https://portal.gdc.cancer.gov/files/750db0c4-d05c-406e-829c-34bc54133251

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 88; copy number 1: 2,830; copy number 2: 26,243; copy number 3: 22,132; copy number 4: 5,347; copy number 5: 1,170; copy number 6: 398; copy number 7: 155; copy number 8: 49; copy number 11: 13; copy number 13: 17; copy number 14: 83; copy number 15: 3; copy number 16: 3; copy number 18: 15; copy number 26: 12; copy number 27: 48; copy number 28: 59; copy number 29: 82; copy number 32: 48; copy number 33: 34; copy number 35: 87.

Homozygous deletions (total copy number 0; autosomes only): 88 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:22,168,429–22,552,156, 88 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,276 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:58,192,257–58,214,697, 1 gene, copy number 5: DNASE1L3.
- chr3:187,668,912–187,670,394, 1 gene, copy number 5: SST.
- chr7:5,306,790–6,551,436, 41 genes, copy number 5 (within-gene range 4–5): TNRC18, AC093620.1, AC092171.1, AC092171.4, AC092171.3, AC092171.5, FBXL18, AC092171.2, MIR589, ACTB, AC006483.2, AC006483.1, FSCN1, RNF216, RNF216-IT1, MIR6874, ZNF815P, RN7SL556P, OCM, CCZ1, RSPH10B, PMS2, Y_RNA, AIMP2, SNORA80D, EIF2AK1, ANKRD61, RN7SL851P, RNU6-218P, AC004895.1, USP42, CYTH3, Y_RNA, FAM220A, AC009412.1, RPSAP73, RAC1, DAGLB, KDELR2, AC072052.1, GRID2IP.
- chr7:38,341,577–38,378,804, 1 gene, copy number 5 (within-gene range 2–5): TRG-AS1.
- chr7:38,358,512–40,860,763, 38 genes, copy number 5 (within-gene range 2–5): TRGV3, TRGV2, TRGV1, AMPH, RN7SL83P, KRT8P20, FAM183BP, VPS41, POU6F2, POU6F2-AS2, SNORA20B, POU6F2-AS1, AC011290.1, YAE1, AC011290.2, AC004837.3, AC004837.1, RALA, AC004837.2, LINC00265, RNU6-719P, AC004987.3, CICP22, AC004987.2, AC004987.1, SSBL3P1, RWDD4P2, RN7SL496P, AC072061.1, CDK13, AC006023.2, AC006023.1, MPLKIP, Y_RNA, SUGCT, THUMPD3P1, SUGCT-AS1, AC005160.1.
- chr7:56,875,385–57,020,273, 5 genes, copy number 5: AC118758.1, AC069152.1, MIR4283-1, TNRC18P3, SLC29A4P1.
- chr7:63,113,635–64,501,729, 85 genes, copy number 15–29 (broad region; genes not listed).
- chr8:52,534,037–126,558,478, 1,071 genes, copy number 5–6 (broad region; genes not listed).
- chr8:126,582,631–126,846,981, 3 genes, copy number 5: AC083923.1, RNU11-4P, AC024382.1.
- chr12:66,767–34,249,958, 831 genes, copy number 6–35 (broad region; genes not listed).
- chr12:131,924,736–132,610,582, 35 genes, copy number 5: AC131009.1, PUS1, AC131009.3, EP400, SNORA49, AC137590.1, AC137590.2, EP400P1, AC138466.5, AC138466.2, DDX51, NOC4L, AC138466.3, LINC02361, AC138466.1, GALNT9, AC138466.4, AC148477.3, AC148477.2, AC148477.5, AC148477.4, AC148477.1, AC148477.7, AC148477.8, AC148477.6, AC148477.9, AC148476.1, AC079031.1, AC079031.2, FBRSL1, AC131212.3, AC131212.2, MIR6763, AC131212.1, LRCOL1.
- chr15:34,084,017–35,546,193, 48 genes, copy number 27: EMC7, AC079203.1, PGBD4, KATNBL1, EMC4, SLC12A6, AC079203.2, Y_RNA, NOP10, NUTM1, LPCAT4, ACTG1P15, GOLGA8A, MIR1233-1, AC025678.1, AC025678.2, AC025678.3, HNRNPLP2, FSCN1P1, DNM1P5, GOLGA8B, MIR1233-2, AC027139.1, AC100834.1, LINC02252, GJD2, AC087457.1, ACTC1, TUBAP11, AQR, AC018868.1, ZNF770, AC114546.3, AC114546.1, AC114546.4, AC114546.2, AC021231.3, NANOGP8, AC021231.2, AC021231.1, PRELID1P4, ANP32AP1, DPH6, NUTF2P6, RBM17P4, MIR3942, AC019288.1, HNRNPA1P45.
- chr15:97,560,849–101,979,093, 116 genes, copy number 7–33 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,888. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
